Somatic mutation profile of tumor specimen TCGA-Y8-A898-01A (aliquot TCGA-Y8-A898-01A-11D-A34Z-10) from TCGA case TCGA-Y8-A898, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.4 years (25,344 days).
Specimen TCGA-Y8-A898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c3d11f2-8edc-458d-8387-b9ec680a0bad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A898-10A (Blood Derived Normal), aliquot TCGA-Y8-A898-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcf6f84e-7980-4406-bada-005ba807600d

The open-access MAF lists 78 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 49, Silent 13, Frame Shift Del 6, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM17 | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100176283, COSV60398330; called by muse, mutect2, varscan2
- ADAM32 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs774445935, COSV101165405, COSV101165494; called by muse, mutect2, varscan2
- ARID4A | c.3447A>T p.K1149N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100794287; called by muse, mutect2, varscan2
- ATG13 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56318883; called by muse, mutect2, varscan2
- C10orf71 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs185740154, COSV100110195; called by muse, mutect2, varscan2
- CCPG1 | c.1364C>G p.A455G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99380406; called by muse, mutect2, varscan2
- CHSY1 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV99573916; called by muse, mutect2, varscan2
- CLEC18A | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as COSV99846952; called by muse, mutect2
- CLEC18A | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs763322283, COSV55344900; called by muse, mutect2
- CNST | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.359); catalogued as rs753311239, COSV100830062; called by muse, mutect2, varscan2
- COL6A5 | c.6271T>C p.Y2091H (on ENST00000312481; = p.Y2087H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550946747, COSV99593280; called by muse, mutect2, varscan2
- COLEC12 | c.2091C>G p.N697K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101232075, COSV68369464; called by muse, mutect2, varscan2
- COPS5 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV100769909; called by muse, mutect2, varscan2
- CTNNA1 | c.443A>C p.Y148S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100242790; called by muse, mutect2, varscan2
- DYNC2H1 | c.10537A>G p.N3513D | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1388399593, COSV100518670; called by muse, mutect2, varscan2
- EID2 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101180486; called by muse, mutect2, varscan2
- ETFB | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs374288379; called by muse, mutect2, varscan2
- FAM110D | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs954831198, COSV100957628; called by muse, mutect2
- FARP2 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.782); catalogued as COSV99884681; called by muse, mutect2, varscan2
- GTF2A1 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.105); catalogued as COSV99993431; called by muse, mutect2, varscan2
- HERC2 | c.8284C>G p.R2762G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs543946257, COSV55321586; called by muse, mutect2, varscan2
- HYDIN | c.6646C>A p.Q2216K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV99992974; called by muse, mutect2, varscan2
- KYAT3 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV53107362, COSV99556239; called by muse, mutect2, varscan2
- LAMA5 | c.4310C>T p.P1437L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99440227; called by muse, mutect2, varscan2
- MADD | c.1025T>A p.M342K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100211472; called by muse, mutect2
- MAP4K2 | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99580997; called by muse, mutect2, varscan2
- MICAL3 | c.2599A>T p.T867S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99261648; called by muse, mutect2, varscan2
- MUC15 | c.991C>A p.R331S | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99846190, COSV99846440; called by muse, mutect2, varscan2
- MYO18B | c.6052C>T p.R2018W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs763836112, COSV100123747; called by muse, mutect2, varscan2
- MYO3A | c.1600G>C p.A534P | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99779815; called by muse, mutect2, varscan2
- NKAIN3 | c.287T>A p.M96K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100133871; called by muse, mutect2, varscan2
- NLRC3 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1363694130, COSV57093060; called by muse, mutect2, varscan2
- NUDT16L1 | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99274231; called by muse, mutect2, varscan2
- PALLD | c.2851-2A>G p.X951_splice (on ENST00000505667 / NM_001166108.2; = p.X934_splice on NM_016081.4) | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99824849; called by muse, mutect2, varscan2
- PLBD2 | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV99785335; called by muse, mutect2, varscan2
- POLM | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99641808; called by muse, mutect2, varscan2
- POLR2K | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100777490; called by muse, mutect2, varscan2
- PRORP | c.1282A>G p.N428D | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99155550; called by muse, mutect2, varscan2
- QSOX2 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as COSV100699770; called by muse, mutect2, varscan2
- RPS6KA2 | c.747+1G>A p.X249_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99690944; called by muse, mutect2, varscan2
- SIK3 | c.3976A>G p.S1326G (on ENST00000445177 / NM_001366686.2; = p.S1284G on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99408080; called by muse, mutect2, varscan2
- SKIV2L | c.1264T>G p.F422V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952757; called by muse, mutect2, varscan2
- SLC35F5 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99829992, COSV99830069; called by muse, mutect2, varscan2
- SLC7A8 | c.388A>T p.I130F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100382378; called by muse, mutect2, varscan2
- SPESP1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464276244, COSV99533908; called by muse, mutect2, varscan2
- SPG11 | c.5377A>C p.K1793Q | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99968739; called by muse, mutect2
- SYNE3 | c.2417T>A p.F806Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100516035, COSV62079958; called by muse, mutect2, varscan2
- TMEM131L | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 83/215 reads (39%) | catalogued as COSV99547481; called by muse, mutect2, varscan2
- TMEM98 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV55583406; called by muse, mutect2, varscan2
- TRMT12 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV100149201; called by muse, mutect2, varscan2
- VPS8 | c.3772T>A p.C1258S (on ENST00000625842 / NM_001349294.1; = p.C1256S on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99802271; called by muse, mutect2, varscan2
- WDFY3 | c.7901G>A p.G2634E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV55705020; called by muse, mutect2, varscan2
- XKR8 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100874579; called by muse, mutect2, varscan2
- ARFGEF3 | c.3425A>C p.Y1142S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.156); called by muse, varscan2
- ARFGEF3 | c.3431_3433del p.L1144_K1145delinsQ | In Frame Del (DEL) | VAF 21/108 reads (19%) | called by pindel, varscan2
- CPA1 | c.258_272del p.Y86_E91delins* | Nonsense Mutation (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- CYLD | c.2458_2467del p.C820Kfs*9 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- EP300 | c.2336del p.N779Ifs*25 | Frame Shift Del (DEL) | VAF 51/190 reads (27%) | called by mutect2, pindel, varscan2
- FRRS1 | c.176_189del p.R59Nfs*2 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- FZD7 | c.1017_1018del p.F340Hfs*225 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- HLA-DOB | c.115dup p.A39Gfs*2 | Frame Shift Ins (INS) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- IGKV1-33 | c.179del p.Q60Rfs*10 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, varscan2
- METTL26 | c.504del p.L169Ffs*31 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- OR6C75 | c.875dup p.N292Kfs*2 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1523_1526dup p.S510Wfs*44 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.2112G>T p.L704= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57935686; called by muse, mutect2, varscan2
- CTNNA1 | c.444C>T p.Y148= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV100242792, COSV57079892; called by muse, mutect2, varscan2
- DDB1 | c.2169G>A p.K723= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100074615; called by muse, mutect2, varscan2
- DMXL1 | c.3249T>C p.C1083= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as COSV100224016; called by muse, mutect2, varscan2
- EBNA1BP2 | c.690C>T p.G230= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs1238128043, COSV99355978; called by muse, mutect2, varscan2
- FNDC1 | c.1797G>A p.K599= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs755328331, COSV99795883; called by muse, mutect2, varscan2
- ITGA6 | c.675T>C p.T225= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs748403545, COSV99905555; called by muse, mutect2, varscan2
- MAGI2 | c.2976G>T p.V992= | Silent (SNP) | VAF 38/198 reads (19%) | catalogued as COSV100834589; called by muse, mutect2, varscan2
- MPL | c.1353G>T p.L451= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100991584; called by muse, mutect2, varscan2
- PLXNB1 | c.2046A>T p.P682= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99602884; called by muse, mutect2
- SLC7A8 | c.387G>A p.V129= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100382380; called by muse, mutect2, varscan2
- VMP1 | c.1218A>G p.K406= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV51871631; called by muse, mutect2
- WDR19 | c.1323T>C p.A441= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99975503; called by muse, mutect2, varscan2
